Surgical pathology report (de-identified scan), TCGA case TCGA-55-7726, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7726-01A (Primary Tumor).

[page 1 of 3]
*** Final Report ***

SURG PATH FINAL REPORT

SURGICAL PATHOLOGY

PROCEDURE

Lung, left lower lobectomy.

SPECIMEN:

A. L9 lymph node. B. left lower lobe lung. C. L10 intralobar.
D. L7.

HISTORY

Left lower lobe (cancer) (mass).

GROSS

A. Labeled "L9 lymph node" is a 0.8 x 0.8 x 0.3 cm rubbery yellow fat which includes a 0.3 cm in diameter, gray-tan rubbery nodule.

B. Labeled "left lower lobe lung" is a rubbery salmon-pink resected left lower lobe of lung, 130 grams and 13.2 x 10.8 x 5 cm. A 2.9 x 2.4 x 1.3 cm firm tan-gray variegated tumor mass, 1.5 cm from the bronchial resection margin, puckers but does not penetrate the pleura of the superior segment. The pleural surface is inked above the tumor. Resection margins of bronchus and blood vessels are grossly unremarkable. Parenchyma away from the tumor is gray and salmon pink, free of additional nodules. Block 1: Frozen section remnant of bronchial margin. Block 2: Resection margins of vessels.

Blocks 3-5: Tumor. Block 6: Representative lung away from tumor. A portion of the tumor is submitted for cancer genome study.

C. Labeled "L10 intralobar" is a 1.2 x 0.8 x 0.3 cm rubbery tan-yellow node, bisected. 2/1

D. Labeled "L/7" is a 0.6 x 0.3 x 0.2 cm rubbery gray-black nodule, bisected. 2/1

FROZEN SECTION DIAGNOSIS

B. Left lower lobe lung, resection:
Bronchial resection margins negative for carcinoma.
(Diagnosis to)

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surg Path Final Report

* Final Report *

MICROSCOPIC

A-D. Performed.

DIAGNOSIS

- A. L9 lymph node, excision biopsy:
One lymph node, negative for metastatic carcinoma.
CPT 88305
- B. Left lower lobe lung, resection:
Adenocarcinoma, poorly differentiated (2.9 cm), previously diagnosed [REDACTED]
Intralymphatic tumor invasion.
Bronchial and vascular resection margins, free of malignancy.
Tumor-associated scar.
Lung parenchyma away from tumor, free of lesion.
CPT 88309,88331
- C. L10 intralobular lymph node, excision biopsy:
One lymph node, negative for metastatic carcinoma.
CPT 88305
- D. L7 lymph node, excision biopsy:
One lymph node, negative for metastatic carcinoma.
[REDACTED]
CPT 88305

SUMMARY OF MALIGNANT NEOPLASM: LUNG

SPECIMEN:	lung lobe
PROCEDURE:	lobectomy
SPECIMEN INTEGRITY:	intact
SPECIMEN LATERALITY:	left
TUMOR SITE:	lower lobe, superior segment
TUMOR SIZE:	2.9 cm
TUMOR FOCALITY:	Unifocal
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	Poorly differentiated
VISCERAL PLEURA INVASION:	visceral pleural not involved
MARGINS:	Not involved; 1.5 cm to closest (bronchial) margin
TREATMENT EFFECT:	Not applicable
LYMPH-VASCULAR INVASION:	Present
LYMPH NODES:	Three of 3 lymph nodes, negative for metastasis
OTHER FINDINGS:	Tumor-associated scar.
PATH TNM(AJCC 7th ed.):	pT1b pN0 Stage IA

COMMENT

Final diagnosis for specimen B corresponds to that given at the time of frozen section examination.

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surg Path Final Report

* Final Report *

Completed Action List:

* Order by

Type:
Date:
Status:
Title:
Encounter info:

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 4bbb92f3-f94e-43eb-9afe-eb7a1c533853 (TCGA-55-7726.094C672B-F6C7-4250-BB17-4D23A48B81C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).